Somatic mutation profile of tumor specimen 0DJGE2 from CCDI case PBBWWW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.6 years (3,489 days).
Specimen 0DJGE2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 540703ac-17c5-4c3f-90ae-49bbf32c288e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJG71 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49758579-7a6c-4b2b-95b8-6c8861ab3471

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCYAP1R1 | c.884+1G>T p.X295_splice | Splice Site (SNP) | VAF 110/565 reads (19%) | called by mutect2, varscan2
- ATP8B3 | c.3435G>A p.A1145= | Silent (SNP) | VAF 36/767 reads (5%) | catalogued as rs1326184473, COSV59548445; called by muse, mutect2
- DDX23 | c.507A>G p.R169= | Silent (SNP) | VAF 179/651 reads (27%) | called by muse, mutect2, varscan2
